Somatic mutation profile of tumor specimen MP2PRT-PATAUA-TMP1-A (aliquot MP2PRT-PATAUA-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATAUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,834 days).
Specimen MP2PRT-PATAUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd88673f-461d-4029-99b4-2c2267f16578.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATAUA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATAUA-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f596038a-26dd-4bff-b1e4-555f594f00b6

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 166/370 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59247867; called by muse, mutect2, varscan2
- ASTL | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 264/537 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757814790; called by muse, mutect2, varscan2
- BAHD1 | c.454del p.H152Tfs*56 | Frame Shift Del (DEL) | VAF 204/558 reads (37%) | catalogued as COSV69083970; called by mutect2, pindel, varscan2
- DPP10 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 141/312 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59683831; called by muse, mutect2, varscan2
- DSCAML1 | c.1957G>A p.V653I (on ENST00000321322; = p.V593I on NM_020693.4) | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs772587336, COSV58380717; called by muse, mutect2, varscan2
- FTHL17 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 222/262 reads (85%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV63266539, COSV63267412; called by muse, mutect2, varscan2
- KLHDC7A | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 126/286 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1216719846, COSV68768971; called by muse, mutect2, varscan2
- MYO1A | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs555972627, COSV55652878; called by muse, mutect2, varscan2
- TBL1XR1 | c.1461T>G p.F487L | Missense Mutation (SNP) | VAF 200/487 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70504262; called by muse, mutect2, varscan2
- UGT2B10 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 127/324 reads (39%) | catalogued as rs374116536, COSV55320398; called by muse, mutect2, varscan2
- KCND2 | c.156_157delinsG p.F52Lfs*45 | Frame Shift Del (DEL) | VAF 206/705 reads (29%) | called by mutect2*, pindel, varscan2*
- NBAS | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PRICKLE2 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLCO1B3 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF217 | c.1118A>T p.K373M | Missense Mutation (SNP) | VAF 246/546 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN3 | c.564G>A p.P188= | Silent (SNP) | VAF 160/429 reads (37%) | catalogued as rs572671316, COSV55184189; called by muse, mutect2, varscan2
- COL22A1 | c.1170C>T p.I390= | Silent (SNP) | VAF 203/440 reads (46%) | catalogued as rs200314173, COSV57346597; called by muse, mutect2, varscan2
- G6PC3 | c.753G>A p.L251= | Silent (SNP) | VAF 198/485 reads (41%) | catalogued as rs569262371; called by muse, mutect2, varscan2
- KCNMA1 | c.1818C>G p.L606= | Silent (SNP) | VAF 196/488 reads (40%) | called by muse, mutect2, varscan2
- SEC14L5 | c.327C>T p.N109= | Silent (SNP) | VAF 138/360 reads (38%) | catalogued as rs375401992; called by muse, mutect2
- TRIM64B | c.795G>A p.V265= | Silent (SNP) | VAF 81/462 reads (18%) | called by muse, varscan2
